Gene-level copy-number profile of tumor specimen TCGA-X8-AAAR-01A from TCGA case TCGA-X8-AAAR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G1; Age at diagnosis: 69.5 years (25,370 days).
Specimen TCGA-X8-AAAR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.fd0e0ad0-81d0-44ab-9eec-b2555f843c65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X8-AAAR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/070753ea-d96e-4bc3-b4aa-cd8ccea4ebb5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 18,785; copy number 2: 39,889; copy number 3: 775; copy number 4: 7; copy number 5: 42; copy number 9: 92; copy number 11: 41; copy number 23: 156; copy number 33: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X8-AAAR-01A-11D-A402-01): tumor purity 0.76, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 359 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,566,964–32,646,050, 182 genes, copy number 23–33 (broad region; genes not listed).
- chr12:32,692,504–32,705,506, 2 genes, copy number 23: AC084824.2, Y_RNA.
- chr17:32,003,110–34,195,937, 72 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr17:40,473,554–41,836,260, 103 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,399. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
